Somatic mutation profile of tumor specimen 0DII4B from CCDI case PBBVRC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,276 days).
Specimen 0DII4B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70f34927-b944-43b9-880b-f6ba36d1c922.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DII39 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cea40942-fcdd-4a6f-990f-fd3299e9783d

The open-access MAF lists 15 somatic variants for this specimen: 4 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 8, Missense Mutation 2, 3'UTR 2, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBLN1 | c.1194C>T p.V398= | Splice Region (SNP) | VAF 231/432 reads (53%) | catalogued as rs770990825; called by muse, mutect2, varscan2
- PKP1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 22/564 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99825068; called by muse, mutect2
- EGR2 | c.1280A>G p.K427R | Missense Mutation (SNP) | VAF 183/435 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NTSR1 | c.270dup p.K91Efs*242 | Frame Shift Ins (INS) | VAF 293/682 reads (43%) | called by mutect2, pindel, varscan2
- AFDN | c.2767T>C p.L923= | Silent (SNP) | VAF 329/1087 reads (30%) | catalogued as rs1018814350; called by muse, mutect2, varscan2
- AGL | c.3915T>C p.I1305= | Silent (SNP) | VAF 291/723 reads (40%) | called by muse, mutect2, varscan2
- COL9A3 | c.414C>T p.R138= | Silent (SNP) | VAF 42/473 reads (9%) | catalogued as rs770415724, COSV59651587; called by muse, mutect2
- CT47B1 | c.273G>A p.T91= | Silent (SNP) | VAF 30/666 reads (5%) | catalogued as rs1245884832; called by muse, mutect2
- H2BC5 | c.333C>T p.A111= | Silent (SNP) | VAF 107/690 reads (16%) | catalogued as rs941288960, COSV56802166; called by muse, mutect2, varscan2
- PPARGC1A | c.1384C>T p.L462= | Silent (SNP) | VAF 37/940 reads (4%) | called by muse, mutect2
- PTGFRN | c.2604C>T p.R868= | Silent (SNP) | VAF 306/657 reads (47%) | catalogued as rs763120740, COSV67797884; called by muse, mutect2, varscan2
- ZNF799 | c.1455C>T p.F485= | Silent (SNP) | VAF 182/437 reads (42%) | called by muse, mutect2, varscan2
- PCYOX1L | c.*5T>C | 3'UTR (SNP) | VAF 11/273 reads (4%) | catalogued as COSV51002506; called by muse, mutect2
- RNASET2 | c.447-85T>C | Intron (SNP) | VAF 29/99 reads (29%) | called by muse, mutect2, varscan2
- SCEL | c.*1C>G | 3'UTR (SNP) | VAF 224/535 reads (42%) | called by muse, mutect2, varscan2
